Somatic mutation profile of tumor specimen MP2PRT-PAVBKW-TMP1-A (aliquot MP2PRT-PAVBKW-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVBKW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,829 days).
Specimen MP2PRT-PAVBKW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7558bea-ade4-4297-ab08-ca11a1e0bd50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVBKW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVBKW-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df35f478-7e1d-4e7f-bb6f-c3588806ca71

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 16, Nonsense Mutation 3, 3'UTR 1, 3'Flank 1, Intron 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs397507518, CM122800; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADAM10 | c.1768G>C p.D590H | Missense Mutation (SNP) | VAF 6/174 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as COSV53049619; called by muse, mutect2
- C4orf33 | c.83G>C p.R28T | Missense Mutation (SNP) | VAF 177/417 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55416604; called by muse, mutect2, varscan2
- CAPG | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 191/436 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV99809541; called by muse, mutect2, varscan2
- CFAP44 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs954945011; called by muse, mutect2, varscan2
- DDX3X | c.1226C>T p.S409F (on ENST00000399959; = p.S410F on NM_001356.5) | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV67863744; called by muse, mutect2
- FBXL14 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 165/437 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV59335797; called by muse, mutect2, varscan2
- FBXO32 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 126/393 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as rs748572958; called by muse, mutect2, varscan2
- FLNA | c.3887G>A p.R1296H | Missense Mutation (SNP) | VAF 25/829 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs863223623; ClinVar: uncertain significance; called by muse, mutect2
- FUCA2 | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 17/436 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs991244160; called by muse, mutect2
- H3C8 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 19/477 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100010159, COSV59952645; called by muse, mutect2
- KIF4A | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 116/310 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs772078243, COSV65533047; called by muse, varscan2
- MAGEA4 | c.668G>A p.W223* | Nonsense Mutation (SNP) | VAF 252/621 reads (41%) | catalogued as COSV99367198; called by muse, mutect2, varscan2
- MAP7 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1370791479, COSV63418620; called by muse, mutect2, varscan2
- MAPK8IP2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 148/452 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs966459526; called by muse, mutect2, varscan2
- MYH1 | c.4255G>C p.E1419Q | Missense Mutation (SNP) | VAF 128/331 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56843473; called by muse, mutect2, varscan2
- MYH13 | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 120/362 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52824068; called by muse, mutect2, varscan2
- NPBWR2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 318/741 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs775894719; called by muse, mutect2, varscan2
- NSD2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as rs1292228347; called by muse, mutect2, varscan2
- OR10AG1 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV56632210, COSV56635374; called by muse, mutect2, varscan2
- PCDHGA8 | c.1422G>C p.L474F | Missense Mutation (SNP) | VAF 228/464 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1444438979; called by muse, mutect2, varscan2
- PROX1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 174/452 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.089); catalogued as COSV99799057; called by muse, mutect2, varscan2
- RYR2 | c.11773C>G p.Q3925E | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as CM097965, COSV63686899; called by muse, mutect2, varscan2
- SCGN | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as rs1423242526, COSV100618896; called by muse, mutect2, varscan2
- SIM1 | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 157/358 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53489388; called by muse, mutect2, varscan2
- SRGAP2 | c.2624C>A p.S875Y (on ENST00000624873 / NM_001170637.4; = p.S876Y on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 163/516 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV55337789; called by muse, mutect2, varscan2
- TBC1D1 | c.1520C>G p.S507C | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54714384; called by muse, mutect2, varscan2
- USP24 | c.2566C>G p.P856A | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV53773577; called by muse, mutect2
- VPS13A | c.3421G>C p.D1141H | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs757753926; called by muse, mutect2, varscan2
- XRN1 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs1026706276, COSV53817650; called by muse, mutect2, varscan2
- ZFAT | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 86/436 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64734083; called by muse, mutect2, varscan2
- ABCA13 | c.8283G>C p.L2761F | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.323); called by muse, mutect2
- AMBRA1 | c.3400G>A p.E1134K (on ENST00000458649 / NM_001367468.1; = p.E1044K on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/285 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ASNS | c.1319A>G p.K440R | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- BBX | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 93/327 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- C8orf58 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 150/373 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD99L2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 123/440 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- CDT1 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.707); called by muse, mutect2
- CHRNB2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 198/445 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- DOCK5 | c.2280G>C p.L760F | Missense Mutation (SNP) | VAF 94/312 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- FHL5 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 101/333 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2
- HPF1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- IARS2 | c.2698G>C p.E900Q | Missense Mutation (SNP) | VAF 126/283 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IGHV3-53 | c.349_350insGGAGAG | In Frame Ins (INS) | VAF 44/172 reads (26%) | called by pindel, varscan2
- IGHV4-39 | chr14:106421704 del CTGTGTGT | Missense Mutation (DEL) | VAF 112/168 reads (67%) | called by pindel, varscan2*
- JMJD1C | c.5341G>A p.D1781N | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MAPK4 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 19/642 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.218); called by muse, mutect2
- NBEA | c.4855C>T p.H1619Y | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2
- NUDT8 | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 90/627 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- OR7C1 | c.136A>T p.I46F | Missense Mutation (SNP) | VAF 136/349 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- RBM23 | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- RNPC3 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TBX10 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 59/509 reads (12%) | called by muse, mutect2, varscan2
- TSPAN19 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TYRP1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 20/492 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.218); called by muse, mutect2
- VGLL3 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 22/559 reads (4%) | called by muse, mutect2
- AOPEP | c.654C>T p.L218= | Silent (SNP) | VAF 25/323 reads (8%) | catalogued as rs777318703; called by muse, mutect2
- CCNB2 | c.90T>C p.I30= | Silent (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- CPS1 | c.3774G>A p.L1258= | Silent (SNP) | VAF 72/224 reads (32%) | catalogued as COSV51810777; called by muse, mutect2, varscan2
- FAM171B | c.6G>A p.A2= | Silent (SNP) | VAF 43/435 reads (10%) | called by muse, mutect2, varscan2
- GFM1 | c.1293C>T p.F431= | Silent (SNP) | VAF 130/322 reads (40%) | called by muse, mutect2, varscan2
- GPR83 | c.219G>C p.L73= | Silent (SNP) | VAF 220/527 reads (42%) | called by muse, mutect2, varscan2
- LPL | c.1242C>T p.Y414= | Silent (SNP) | VAF 14/438 reads (3%) | catalogued as COSV100255602; called by muse, mutect2
- MUC5B | c.4338C>G p.L1446= | Silent (SNP) | VAF 18/706 reads (3%) | catalogued as COSV71591235; called by muse, mutect2
- NPFFR2 | c.552C>G p.L184= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as COSV58146250; called by muse, mutect2, varscan2
- PRRG3 | c.102A>C p.R34= | Silent (SNP) | VAF 307/735 reads (42%) | called by muse, mutect2, varscan2
- SPRR1B | c.264G>A p.Q88= | Silent (SNP) | VAF 111/344 reads (32%) | catalogued as COSV61068108; called by muse, mutect2, varscan2
- SRGAP2 | c.2625C>A p.S875= (on ENST00000624873 / NM_001170637.4; = p.S876= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 163/513 reads (32%) | called by muse, mutect2, varscan2
- TAF4 | c.2832C>T p.L944= | Silent (SNP) | VAF 67/469 reads (14%) | catalogued as rs1297541125, COSV53343133; called by muse, mutect2, varscan2
- TSC22D3 | c.255C>T p.I85= | Silent (SNP) | VAF 35/729 reads (5%) | catalogued as COSV59778497; called by muse, mutect2
- UBE2L6 | c.165C>T p.I55= | Silent (SNP) | VAF 63/356 reads (18%) | catalogued as COSV54703609; called by muse, mutect2, varscan2
- ZNF23 | c.330G>A p.V110= | Silent (SNP) | VAF 110/282 reads (39%) | called by muse, mutect2, varscan2
- IGKV3-20 | chr2:89142573 ins CGGA | 3'Flank (INS) | VAF 54/186 reads (29%) | called by mutect2, pindel, varscan2
- REXO1L1P | n.788C>T | RNA (SNP) | VAF 91/752 reads (12%) | catalogued as rs747696665; called by muse, mutect2, varscan2
- SLC6A17 | c.*1609G>A | 3'UTR (SNP) | VAF 181/457 reads (40%) | called by muse, mutect2, varscan2
- TTN | c.34264+4792G>C | Intron (SNP) | VAF 46/106 reads (43%) | catalogued as COSV59941392; called by muse, mutect2, varscan2
